Gene-level copy-number profile of tumor specimen C3L-06430-07 from CPTAC case C3L-06430, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 67.1 years (24,514 days).
Specimen C3L-06430-07: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e825c6a7-5a63-4422-9866-9f0990d44dc8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06430-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/74d7ce6d-403f-4e44-9936-41cb6e174a3a

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 521; copy number 1: 2; copy number 2: 43; copy number 3: 13,127; copy number 4: 13,639; copy number 5: 20,200; copy number 6: 4,742; copy number 7: 5,074; copy number 8: 984; copy number 9: 25; copy number 10: 176; copy number 12: 44; copy number 13: 102; copy number 14: 7; copy number 15: 30; copy number 16: 2; copy number 17: 134; copy number 20: 62.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:118,687,752–118,764,345, 3 genes: AL355592.1, LINC02578, TUBB4BP6.
- chr10:128,912,810–128,960,062, 2 genes: LINC02667, AL355537.1.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 337 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:122,318,411–122,886,759, 1 gene, copy number 12 (within-gene range 10–12): CADPS2.
- chr7:122,676,580–125,482,966, 43 genes, copy number 12 (within-gene range 10–12): AC006463.1, RPS26P31, RNF133, RNF148, AC004986.1, TAS2R16, AC073311.1, SLC13A1, LYPLA1P1, IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P, HYAL6P, HYAL4, SPAM1, AC004690.1, AC004690.2, TMEM229A, AC006148.1, AC006148.2, AC004930.1, SSU72P8, AC005521.1, RNU6-102P, AC004925.1, GPR37, C7orf77, POT1, POT1-AS1, EEF1GP1, LINC02830, AC019155.1, AC019155.2, AC010099.1, AC010099.2, PPIAP93.
- chr7:132,123,332–132,648,688, 3 genes, copy number 13–16: PLXNA4, AC018643.1, AC011625.1.
- chr7:133,253,073–134,066,589, 1 gene, copy number 17 (within-gene range 10–17): EXOC4.
- chr7:133,727,368–134,579,875, 10 genes, copy number 17: COX5BP3, RPS3AP27, LRGUK, AC008154.2, SLC35B4, AC008154.1, AC009275.1, AKR1B1, AKR1B10, AKR1B15.
- chr7:134,986,508–143,730,409, 279 genes, copy number 13–20 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
